CPTAC case C3L-01681 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8eb888ed-42e4-4109-8636-4e43503728d9

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1941; Vital status: Dead; Days to death: 1,534 days (4.2 years); Year of death: 2021; Country of birth: United States.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 76.1 years (27,785 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Tumor grade: G3; Residual disease: RX; Days to last known disease status: 1,534 days (4.2 years); Days to last follow up: 1,534 days (4.2 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4.5 cm (a second GDC size field records 3.5 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 2; Margin status: Uninvolved; Sarcomatoid present: No.

Follow-up (6 entries)
- Days to follow up: 368 days (1.0 years); Disease response: Tumor Free.
- Days to follow up: 761 days (2.1 years); Disease response: Tumor Free.
- Days to follow up: 1,168 days (3.2 years); Disease response: Tumor Free.
- Days to follow up: 1,448 days (4.0 years); Disease response: Complete Response.
- Days to follow up: 1,448 days (4.0 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 1,534.

Other clinical attributes
- Weight: 86.18 kg; Height: 177.8 cm; BMI: 27.26.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 5.4; Cigarettes per day: 4; Tobacco smoking onset year: 1954; Tobacco smoking quit year: 1981; Alcohol history: Yes; Alcohol intensity: Non-Drinker; Exposure duration years: 27; Secondhand smoke as child: Yes; Type of smoke exposure: Smoke exposure, NOS.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-01681-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -8 days; Initial weight: 501 mg; Time between excision and freezing: 20 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-01681-26: Section location: Middle; Percent tumor nuclei: 90; Percent necrosis: 0.
- Sample C3L-01681-04: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -8 days; Initial weight: 1,169 mg; Time between excision and freezing: 23 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-01681-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -8 days; Method of sample procurement: Blood Draw.
